Somatic mutation profile of tumor specimen TCGA-14-1823-01A (aliquot TCGA-14-1823-01A-01W-0643-08) from TCGA case TCGA-14-1823, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.5 years (21,384 days).
Specimen TCGA-14-1823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 496d39e7-ba1c-4b38-aede-882364ff730d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1823-10A (Blood Derived Normal), aliquot TCGA-14-1823-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1bed8e7-37a4-497c-9aee-4a37d51fb492

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR8 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770118342, COSV51639089; called by muse, mutect2, varscan2
- ANO7 | c.1708G>A p.V570I (on ENST00000274979; = p.V516I on NM_001370694.2) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs148576854; called by muse, mutect2, varscan2
- AURKB | c.475dup p.R159Pfs*15 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs745673717; called by pindel, varscan2
- COBLL1 | c.2864A>G p.Y955C (on ENST00000392717; = p.Y917C on NM_014900.5) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779338264, COSV52077688; called by muse, mutect2
- COL4A6 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1410518407; called by muse, mutect2
- DDX58 | c.2698G>A p.G900R | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV59384174; called by muse, mutect2, varscan2
- DDX60 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767373127, COSV67095656; called by muse, mutect2, varscan2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as rs1259961080, COSV55934682; called by muse, mutect2, varscan2
- EMC1 | c.2741A>G p.Q914R | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64346821; called by muse, mutect2
- FERD3L | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs752444969, COSV51761506; called by muse, mutect2, varscan2
- FLG | c.3668A>G p.D1223G | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs185500015; called by muse, mutect2, varscan2
- FZD1 | c.474A>T p.K158N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.951); catalogued as COSV55313804; called by muse, mutect2, varscan2
- GZMB | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV53543947; called by muse, mutect2, varscan2
- HUWE1 | c.7081G>A p.G2361R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs1556943291, COSV53351450; called by muse, mutect2, varscan2
- KCNQ5 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV59686504; called by muse, mutect2, varscan2
- LRP12 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV52635579; called by muse, mutect2, varscan2
- MUC17 | c.10679C>G p.T3560S | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV60306834; called by muse, varscan2
- NKIRAS1 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66248943; called by muse, mutect2, varscan2
- NUP214 | c.2033C>G p.S678C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV63913679; called by muse, mutect2, varscan2
- OGG1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1343218116, COSV56540704; called by muse, mutect2, varscan2
- OR6C6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs757658611, COSV64456046; called by muse, mutect2, varscan2
- PGAP4 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV66388532; called by muse, mutect2, varscan2
- PSD3 | c.2555T>C p.L852S (on ENST00000440756; = p.L851S on NM_015310.4) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489813175, COSV54082200; called by muse, mutect2, varscan2
- SPATA31A1 | c.3430C>A p.Q1144K | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.101); catalogued as COSV100885083; called by muse, mutect2, varscan2
- SSX1 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 29/386 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV65355648, COSV65356546; called by muse, mutect2
- UPP1 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 68/912 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV57978841; called by muse, mutect2
- UPP1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV57978849; called by muse, mutect2
- ZIM3 | c.296G>C p.S99T | Missense Mutation (SNP) | VAF 45/367 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.227); catalogued as COSV54147372; called by muse, mutect2, varscan2
- ZNF257 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV104436097, COSV71306556; called by muse, mutect2, varscan2
- CAST | c.450+1G>A p.X150_splice (on ENST00000341926; = p.X233_splice on NM_001750.7 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2
- EGF | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IPMK | c.174C>G p.Y58* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | called by muse, varscan2
- SAXO2 | c.957C>G p.F319L | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- VARS1 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- ADAMTS12 | c.4014G>A p.V1338= | Silent (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- CACNA1S | c.786G>A p.R262= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV62940614; called by muse, mutect2, varscan2
- CDS2 | c.519C>A p.L173= | Silent (SNP) | VAF 32/360 reads (9%) | called by muse, mutect2
- CFAP100 | c.801G>T p.S267= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV61502891; called by muse, mutect2, varscan2
- LGI3 | c.843G>T p.V281= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV60444503; called by muse, mutect2, varscan2
- NFX1 | c.2598G>A p.P866= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs748822455, COSV59313685; called by muse, mutect2, varscan2
- OTUD6A | c.600C>T p.Y200= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV57973362; called by muse, mutect2
- P2RY10 | c.444C>T p.Y148= | Silent (SNP) | VAF 77/437 reads (18%) | catalogued as rs773170972, COSV50680680, COSV50682260; called by muse, mutect2, varscan2
- PKHD1 | c.11817G>T p.V3939= | Silent (SNP) | VAF 16/355 reads (5%) | catalogued as COSV64396726; called by muse, mutect2
- STX4 | c.714C>T p.I238= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- VPS13A | c.2175T>C p.D725= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as COSV62440860; called by muse, mutect2, varscan2
